MMRF case MMRF_2468 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/090e97b2-6ce5-47fe-a0fa-dad892d9f9cb

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.1 years (21,966 days); ISS stage: III; Days to last known disease status: 712 days (1.9 years); Days to last follow up: 712 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 358 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 220 days; Days to treatment end: 221 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 222 days; Days to treatment end: 222 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1430 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.102 mg/dL; Immunoglobulin G 3.66 g/L; Immunoglobulin A 0.303 g/L; Immunoglobulin M 0.0672 g/L; Beta 2 Microglobulin 7.51 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.98 ×10⁹/L; Absolute Neutrophil 4.34 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 137 µmol/L; Calcium 2.78 mmol/L; Albumin 40.4 g/L; Total Protein 6.4 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0.024 mg/dL.
- Day 98 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 4.69 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 94.6 µmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 166 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 3.66 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.417 g/L; Lactate Dehydrogenase 4.45 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.22 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 97.2 µmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 250 (ECOG 1): Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.23 ×10⁹/L; Absolute Neutrophil 5.04 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 113 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7.31 g/dL; Glucose 5.94 mmol/L.
- Day 348 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.33 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 90.2 µmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 5.01 mmol/L.
- Day 446 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 2.45 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7.31 ×10⁹/L; Absolute Neutrophil 3.62 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 537 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 5.67 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.78 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 113 µmol/L; Calcium 2.6 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.6 mmol/L.
- Day 621 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 4.91 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.68 ×10⁹/L; Absolute Neutrophil 2.78 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 120 µmol/L; Calcium 2.45 mmol/L; Albumin 35.9 g/L; Total Protein 6.9 g/dL; Glucose 6.66 mmol/L.
- Day 712 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.26 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 2.9 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.11 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 91.9 µmol/L; Calcium 2.5 mmol/L; Albumin 36.8 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -19: Weight: 75 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2468_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2468_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
